Somatic mutation profile of tumor specimen TCGA-EK-A2PI-01A (aliquot TCGA-EK-A2PI-01A-11D-A18J-09) from TCGA case TCGA-EK-A2PI, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 44.7 years (16,324 days).
Specimen TCGA-EK-A2PI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 77053058-d287-4253-879c-74917f49dea9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EK-A2PI-10A (Blood Derived Normal), aliquot TCGA-EK-A2PI-10A-01D-A18J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b5adfa9a-2177-4e46-9c24-bc770e794571

The open-access MAF lists 84 somatic variants for this specimen: 62 protein-altering or splice-affecting, 21 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 21, Nonsense Mutation 4, Nonstop Mutation 1, Frame Shift Del 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.229G>C p.D77H | Missense Mutation (SNP) | VAF 56/148 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67960000, COSV67960068, COSV67960466; called by muse, mutect2, varscan2
- AKAP13 | c.4066G>A p.E1356K | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100773408; called by muse, mutect2
- ARHGAP28 | c.2141G>A p.R714H (on ENST00000383472 / NM_001366230.1; = p.R555H on NM_001010000.3) | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs374272304; called by muse, mutect2, varscan2
- ATR | c.5806C>T p.H1936Y | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.729); catalogued as rs1423713950, COSV63383303; called by muse, mutect2, varscan2
- BACH1 | c.1756G>A p.E586K | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV54516994; called by muse, mutect2, varscan2
- BAHCC1 | c.2068G>A p.D690N | Missense Mutation (SNP) | VAF 22/31 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as rs566509890, COSV57022241; called by muse, mutect2, varscan2
- BBS12 | c.1190C>T p.A397V | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.74); PolyPhen benign (0.015); catalogued as rs369235456; called by mutect2, varscan2
- BST1 | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.113); catalogued as rs113632818, COSV53945345; called by muse, mutect2, varscan2
- C9orf153 | c.130A>C p.K44Q | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.046); catalogued as COSV59250445; called by muse, mutect2, varscan2
- CCDC114 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); catalogued as rs774866725, COSV59554973; called by muse, mutect2, varscan2
- CDC45 | c.326T>C p.V109A | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.423); catalogued as COSV54243188; called by muse, mutect2, varscan2
- CDH12 | c.1912C>T p.R638* | Nonsense Mutation (SNP) | VAF 22/74 reads (30%) | catalogued as COSV66385895; called by muse, mutect2, varscan2
- CGB8 | c.7A>T p.M3L | Missense Mutation (SNP) | VAF 10/179 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV100031980; called by muse, mutect2
- CHKA | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs368477871; called by muse, mutect2, varscan2
- COL25A1 | c.485G>A p.G162E | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101211503, COSV67645802; called by mutect2, varscan2
- CROCC | c.4478C>T p.P1493L | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.31); PolyPhen benign (0.316); catalogued as COSV65009640; called by muse, mutect2, varscan2
- CWF19L1 | c.688G>C p.G230R | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.813); catalogued as COSV62498891; called by mutect2, varscan2
- DENND5B | c.2935G>A p.E979K | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV60899476; called by muse, mutect2, varscan2
- DNAJC6 | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); catalogued as rs759567966, COSV54768935; called by muse, mutect2, varscan2
- EFCAB6 | c.2168G>T p.S723I | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.641); catalogued as COSV53057336; called by muse, mutect2, varscan2
- EGF | c.2752C>G p.L918V | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.543); catalogued as COSV54475237; called by muse, mutect2, varscan2
- EVA1A | c.397G>C p.E133Q | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751887683, COSV52056450; called by muse, mutect2, varscan2
- FBXW2 | c.684G>A p.A228= | Splice Region (SNP) | VAF 16/29 reads (55%) | catalogued as rs200239627; called by muse, mutect2, varscan2
- GNA15 | c.788A>G p.E263G | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.503); catalogued as COSV53584771; called by muse, mutect2, varscan2
- GPLD1 | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.419); catalogued as COSV57753689; called by muse, mutect2, varscan2
- HLA-DRA | c.595C>A p.L199I | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV66622463, COSV66622746; called by muse, mutect2, varscan2
- HTT | c.5057A>C p.Q1686P | Missense Mutation (SNP) | VAF 41/63 reads (65%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV61856803; called by muse, mutect2, varscan2
- IDI2 | c.383T>C p.I128T | Missense Mutation (SNP) | VAF 30/41 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1232946103, COSV52986947; called by muse, mutect2, varscan2
- IFT52 | c.664C>G p.Q222E | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV65974352; called by muse, mutect2, varscan2
- IGDCC4 | c.3671G>A p.G1224E | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.038); catalogued as COSV61535185; called by muse, mutect2, varscan2
- IGHE | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1555457066; called by muse, mutect2, varscan2
- KIF1B | c.4149G>A p.M1383I (on ENST00000377086 / NM_001365952.1; = p.M1337I on NM_015074.3) | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV55802783, COSV55806256; called by muse, mutect2, varscan2
- KIF27 | c.1756G>A p.D586N | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.118); catalogued as COSV52824779, COSV52832177; called by muse, mutect2, varscan2
- KRT6B | c.1051G>C p.E351Q | Missense Mutation (SNP) | VAF 49/109 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV52881664, COSV52887048; called by muse, mutect2, varscan2
- LARS2 | c.239C>T p.S80L | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs374194205; called by muse, mutect2, varscan2
- LDAH | c.735G>A p.M245I | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV52968177; called by muse, mutect2, varscan2
- LPL | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs199675233, HM971397, COSV60929796; called by muse, mutect2, varscan2
- MMP2 | c.1295G>C p.R432P | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.999); catalogued as rs780391868, COSV54598756; called by muse, mutect2, varscan2
- NAIP | c.660G>C p.W220C | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52000411, COSV99519159; called by muse, mutect2, varscan2
- OR8H3 | c.232G>A p.V78I | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755802863, COSV57907234; called by muse, mutect2, varscan2
- PCDHA13 | c.1823C>T p.S608L | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.909); catalogued as COSV56474759; called by muse, mutect2, varscan2
- PDE3A | c.1122G>C p.L374F | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62966940; called by muse, mutect2, varscan2
- PHC3 | c.20C>T p.P7L (on ENST00000494943 / NM_001308116.2; = p.P19L on NM_024947.4) | Missense Mutation (SNP) | VAF 46/184 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs368703405, COSV71923598; called by muse, mutect2, varscan2
- PHKA2 | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs1202167585, COSV66052129; called by muse, mutect2, varscan2
- PIP5K1C | c.998G>A p.R333Q | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs115148108, COSV100095209; called by muse, mutect2, varscan2
- PLCH1 | c.2455C>T p.R819* (on ENST00000340059 / NM_001130960.2; = p.R831* on NM_014996.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 13/70 reads (19%) | catalogued as rs773951695, COSV58184975; called by muse, mutect2, varscan2
- PLS1 | c.1888T>G p.*630Eext*81 | Nonstop Mutation (SNP) | VAF 30/105 reads (29%) | catalogued as COSV61832538; called by muse, mutect2, varscan2
- PTPN12 | c.772G>C p.E258Q | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV50354000; called by muse, mutect2, varscan2
- PUS7 | c.1700A>G p.D567G | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV62675647; called by muse, mutect2, varscan2
- RADX | c.788C>G p.T263S | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV100998804; called by muse, mutect2, varscan2
- RFX7 | c.70G>A p.E24K (on ENST00000559447 / NM_001368074.1; = p.E121K on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV57959191; called by muse, mutect2, varscan2
- RRN3 | c.50C>A p.S17* | Nonsense Mutation (SNP) | VAF 43/128 reads (34%) | catalogued as COSV52213015; called by muse, mutect2, varscan2
- RTN4RL2 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58651158; called by muse, mutect2, varscan2
- SETDB1 | c.3631G>C p.D1211H | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99644241; called by muse, mutect2
- SRCAP | c.3586C>T p.R1196C | Missense Mutation (SNP) | VAF 41/76 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs375393051, COSV52666865; called by muse, mutect2, varscan2
- TERT | c.1466G>A p.R489K | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.039); catalogued as COSV99717550, COSV99719515; called by muse, mutect2
- TONSL | c.1393G>A p.E465K | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT tolerated (0.87); PolyPhen benign (0.122); catalogued as COSV68047503; called by muse, mutect2, varscan2
- TRIM67 | c.1208G>A p.R403H | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.188); catalogued as rs372931843; called by muse, mutect2, varscan2
- TSPYL4 | c.919C>T p.R307* | Nonsense Mutation (SNP) | VAF 14/37 reads (38%) | catalogued as rs1484148404, COSV60305656; called by muse, mutect2, varscan2
- TSSK4 | c.533C>T p.P178L | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.053); catalogued as rs760082859, COSV55302227; called by muse, mutect2, varscan2
- ZNF793 | c.229C>T p.H77Y | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.042); catalogued as COSV71324786; called by muse, mutect2, varscan2
- TMEM120A | c.1022del p.K341Rfs*68 | Frame Shift Del (DEL) | VAF 16/49 reads (33%) | called by mutect2, pindel, varscan2
- AATK | c.2925C>T p.P975= (on ENST00000326724 / NM_001080395.3; = p.P872= on NM_004920.2) | Silent (SNP) | VAF 38/96 reads (40%) | catalogued as COSV58363675; called by muse, mutect2, varscan2
- ADAM22 | c.1071G>C p.V357= | Silent (SNP) | VAF 39/107 reads (36%) | catalogued as COSV55968700; called by muse, mutect2, varscan2
- ARHGAP28 | c.669G>A p.L223= (on ENST00000383472 / NM_001366230.1; = p.L64= on NM_001010000.3) | Silent (SNP) | VAF 7/71 reads (10%) | catalogued as rs1390326967, COSV99149251; called by muse, mutect2
- BFSP1 | c.1149C>T p.N383= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as rs758874244, COSV64899199; called by muse, mutect2, varscan2
- CEP152 | c.4236G>A p.K1412= (on ENST00000380950 / NM_001194998.2; = p.K1356= on NM_014985.4) | Silent (SNP) | VAF 22/42 reads (52%) | catalogued as COSV57856258; called by muse, mutect2, varscan2
- CHRD | c.2235G>A p.P745= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as rs764300411, COSV52605014; called by muse, mutect2, varscan2
- CYP4V2 | c.324G>T p.V108= | Silent (SNP) | VAF 25/52 reads (48%) | catalogued as COSV66504825; called by muse, mutect2
- GFRA1 | c.1332G>C p.L444= | Silent (SNP) | VAF 31/69 reads (45%) | catalogued as COSV62601431; called by muse, mutect2, varscan2
- GPRASP1 | c.1599T>G p.G533= | Silent (SNP) | VAF 64/136 reads (47%) | catalogued as COSV100850958; called by muse, mutect2, varscan2
- GRIN2A | c.2580C>G p.L860= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV58018322; called by muse, mutect2, varscan2
- HAPLN4 | c.693C>T p.G231= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as rs913299782, COSV52268254; called by muse, mutect2, varscan2
- KRT4 | c.1029A>G p.Q343= | Silent (SNP) | VAF 40/117 reads (34%) | catalogued as COSV53405434; called by muse, mutect2, varscan2
- KRTAP10-1 | c.129G>C p.L43= | Silent (SNP) | VAF 60/165 reads (36%) | catalogued as COSV59950281; called by muse, mutect2, varscan2
- MYH10 | c.1191G>C p.L397= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV52594389; called by muse, mutect2, varscan2
- NYNRIN | c.5679C>T p.F1893= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV66840927; called by muse, mutect2, varscan2
- PCDHA13 | c.1824G>A p.S608= | Silent (SNP) | VAF 23/102 reads (23%) | catalogued as rs1443036011, COSV56474765; called by muse, mutect2, varscan2
- PCDHGA12 | c.2121C>T p.F707= | Silent (SNP) | VAF 6/136 reads (4%) | catalogued as rs865848752, COSV52750761; called by muse, mutect2
- PRR27 | c.87C>T p.D29= | Silent (SNP) | VAF 6/85 reads (7%) | catalogued as COSV100748777; called by muse, mutect2
- RRP15 | c.153G>A p.S51= | Silent (SNP) | VAF 17/22 reads (77%) | catalogued as rs145914864, COSV65117205; called by muse, mutect2, varscan2
- TRRAP | c.6039C>T p.V2013= (on ENST00000359863 / NM_001244580.1; = p.V1995= on NM_003496.3) | Silent (SNP) | VAF 35/89 reads (39%) | catalogued as COSV100722278; called by muse, mutect2, varscan2
- ZNF318 | c.3837G>A p.K1279= | Silent (SNP) | VAF 25/35 reads (71%) | catalogued as COSV58929885; called by muse, mutect2, varscan2
- FUT11 | c.1335-49C>G | Intron (SNP) | VAF 30/75 reads (40%) | catalogued as COSV59539428; called by muse, mutect2, varscan2
